Somatic mutation profile of tumor specimen TCGA-13-0920-01A (aliquot TCGA-13-0920-01A-01W-0420-08) from TCGA case TCGA-13-0920, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 65.9 years (24,064 days).
Specimen TCGA-13-0920-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1c3c085e-b999-4e30-a3c7-38168a41265a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-13-0920-10A (Blood Derived Normal), aliquot TCGA-13-0920-10A-01W-0420-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/37957631-37ac-4144-97e9-7eee22a643bb

The open-access MAF lists 295 somatic variants for this specimen: 218 protein-altering or splice-affecting, 69 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 183, Silent 69, Nonsense Mutation 13, Frame Shift Del 8, Splice Site 7, In Frame Del 5, RNA 5, Intron 2, Splice Region 1, 3'Flank 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.298C>T p.Q100* | Nonsense Mutation (SNP) | VAF 178/246 reads (72%) | catalogued as rs1567555994, CM156961, COSV52702138, COSV53867973; ClinVar: pathogenic; called by muse, mutect2, varscan2
- A2ML1 | c.3558G>T p.W1186C | Missense Mutation (SNP) | VAF 17/198 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100229169; called by muse, mutect2
- ABCA13 | c.10711T>A p.F3571I | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs992478979, COSV101446954, COSV101447046; called by muse, mutect2, varscan2
- ABCC10 | c.4183G>T p.A1395S (on ENST00000372530 / NM_001198934.2; = p.A1367S on NM_033450.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 33/185 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55084272; called by muse, mutect2, varscan2
- ABCC9 | c.1682C>A p.A561D | Missense Mutation (SNP) | VAF 17/208 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.062); catalogued as COSV99686305; called by muse, mutect2
- ABL1 | c.3001G>T p.A1001S | Missense Mutation (SNP) | VAF 12/160 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.595); catalogued as COSV100584296; called by muse, mutect2
- ACP6 | c.238C>G p.L80V | Missense Mutation (SNP) | VAF 12/125 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100984234; called by muse, mutect2, varscan2
- ADAM19 | c.2050C>T p.P684S | Missense Mutation (SNP) | VAF 13/22 reads (59%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as COSV57422572, COSV57441331; called by muse, mutect2, varscan2
- ADGRE3 | c.1920+1G>T p.X640_splice | Splice Site (SNP) | VAF 19/272 reads (7%) | catalogued as COSV99506439; called by muse, mutect2
- ADGRL3 | c.2474C>T p.T825M (on ENST00000506720 / NM_001322402.2; = p.T757M on NM_015236.6) | Missense Mutation (SNP) | VAF 16/316 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs746668174, COSV72229218; called by muse, mutect2
- ADPRM | c.84T>G p.F28L | Missense Mutation (SNP) | VAF 18/271 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.031); catalogued as COSV101126080; called by muse, mutect2
- AHNAK | c.16762T>G p.L5588V | Missense Mutation (SNP) | VAF 127/607 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV57203333; called by muse, mutect2, varscan2
- AKR1B15 | c.416A>G p.H139R | Missense Mutation (SNP) | VAF 22/574 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV101423393; called by muse, mutect2
- AKR1C1 | c.562T>G p.C188G | Missense Mutation (SNP) | VAF 18/576 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101080514, COSV101080581; called by muse, mutect2
- ALB | c.701C>A p.A234D | Missense Mutation (SNP) | VAF 31/270 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.669); catalogued as COSV55735709; called by muse, mutect2, varscan2
- ANKFY1 | c.2426T>G p.V809G (on ENST00000341657 / NM_001330063.2; = p.V810G on NM_016376.5) | Missense Mutation (SNP) | VAF 15/242 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.272); catalogued as rs1299441630, COSV100492894; called by muse, mutect2
- ANKRD29 | c.379G>A p.V127M | Missense Mutation (SNP) | VAF 45/339 reads (13%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.999); catalogued as rs1204906985, COSV99409239; called by muse, mutect2, varscan2
- ARHGEF19 | c.2363A>C p.K788T | Missense Mutation (SNP) | VAF 132/326 reads (40%) | SIFT tolerated (0.38); PolyPhen benign (0.179); catalogued as COSV54615004; called by muse, mutect2, varscan2
- ARSJ | c.391A>G p.T131A | Missense Mutation (SNP) | VAF 12/104 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.9); catalogued as COSV100192876; called by muse, mutect2, varscan2
- ASTL | c.676A>C p.M226L | Missense Mutation (SNP) | VAF 9/303 reads (3%) | SIFT tolerated (0.73); PolyPhen benign (0.114); catalogued as COSV100668402; called by muse, mutect2
- ATAT1 | c.742G>C p.E248Q | Missense Mutation (SNP) | VAF 14/93 reads (15%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.584); catalogued as COSV53312535; called by muse, mutect2, varscan2
- BEND2 | c.826G>C p.V276L | Missense Mutation (SNP) | VAF 44/236 reads (19%) | SIFT tolerated (0.12); PolyPhen benign (0.009); catalogued as COSV101192113; called by muse, mutect2, varscan2
- BEND2 | c.145G>A p.V49I | Missense Mutation (SNP) | VAF 19/126 reads (15%) | SIFT tolerated, low confidence (0.85); PolyPhen benign (0); catalogued as COSV66214992; called by muse, mutect2, varscan2
- BNC2 | c.1145C>G p.P382R | Missense Mutation (SNP) | VAF 51/182 reads (28%) | SIFT tolerated (0.14); PolyPhen benign (0.104); catalogued as rs761522806, COSV66140586; called by muse, mutect2, varscan2
- C5 | c.2204C>T p.A735V | Missense Mutation (SNP) | VAF 24/420 reads (6%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.688); catalogued as COSV99798285; called by muse, mutect2
- CACFD1 | c.209T>G p.I70S | Missense Mutation (SNP) | VAF 12/130 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.522); catalogued as COSV99390370; called by muse, mutect2, varscan2
- CACHD1 | c.1165A>T p.T389S | Missense Mutation (SNP) | VAF 55/211 reads (26%) | SIFT tolerated (0.33); PolyPhen benign (0.428); catalogued as COSV99262734; called by muse, mutect2, varscan2
- CASS4 | c.760A>T p.S254C | Missense Mutation (SNP) | VAF 9/94 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.533); catalogued as COSV64385367; called by muse, mutect2, varscan2
- CCDC40 | c.2330G>T p.W777L | Missense Mutation (SNP) | VAF 9/107 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV100884281; called by muse, mutect2
- CCL21 | c.98T>C p.L33P | Missense Mutation (SNP) | VAF 15/165 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99425626; called by muse, mutect2
- CCN3 | c.864G>C p.K288N | Missense Mutation (SNP) | VAF 8/138 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); catalogued as COSV52383019; called by muse, mutect2
- CDC23 | c.1364G>A p.C455Y | Missense Mutation (SNP) | VAF 16/188 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV101203133; called by muse, mutect2
- CDH8 | c.43C>A p.P15T | Missense Mutation (SNP) | VAF 49/218 reads (22%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0.079); catalogued as COSV54847529; called by muse, mutect2, varscan2
- CDK5RAP2 | c.4728G>A p.E1576= | Splice Region (SNP) | VAF 12/170 reads (7%) | catalogued as COSV100575609; called by muse, mutect2
- CDKAL1 | c.661T>A p.C221S | Missense Mutation (SNP) | VAF 13/118 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV51179685; called by muse, mutect2, varscan2
- CFAP100 | c.47A>T p.D16V | Missense Mutation (SNP) | VAF 21/107 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.039); catalogued as COSV100729322; called by muse, mutect2, varscan2
- CFAP94 | c.1333G>T p.V445L (on ENST00000320267 / NM_001352064.2; = p.V451L on NM_018272.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 26/100 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); catalogued as COSV57230816; called by muse, mutect2, varscan2
- CGN | c.3409G>A p.E1137K | Missense Mutation (SNP) | VAF 35/261 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54967840; called by muse, mutect2, varscan2
- CHRNA2 | c.181C>T p.R61W | Missense Mutation (SNP) | VAF 128/184 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs142375828; called by muse, mutect2, varscan2
- CLVS1 | c.857C>T p.T286M | Missense Mutation (SNP) | VAF 61/374 reads (16%) | SIFT tolerated (0.19); PolyPhen benign (0.125); catalogued as rs148453129, COSV57972301; called by muse, mutect2, varscan2
- CNGA3 | c.1775C>A p.P592H | Missense Mutation (SNP) | VAF 22/100 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99735981, COSV99736913; called by muse, mutect2, varscan2
- CNNM4 | c.716G>T p.G239V | Missense Mutation (SNP) | VAF 25/108 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV65660200; called by muse, mutect2, varscan2
- CNTROB | c.2074G>T p.D692Y | Missense Mutation (SNP) | VAF 26/837 reads (3%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.495); catalogued as COSV100972718; called by muse, mutect2
- COL4A6 | c.1450T>A p.C484S | Missense Mutation (SNP) | VAF 24/134 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100564528; called by muse, mutect2, varscan2
- COPS7A | c.478C>T p.R160W | Missense Mutation (SNP) | VAF 25/343 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99976403; called by muse, mutect2
- CSPP1 | c.985G>T p.D329Y (on ENST00000676605; = p.D288Y on NM_024790.6) | Missense Mutation (SNP) | VAF 15/131 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.232); catalogued as COSV51580050; called by mutect2, varscan2
- CTAGE1 | c.1490C>A p.S497* | Nonsense Mutation (SNP) | VAF 19/671 reads (3%) | catalogued as COSV101194607; called by muse, mutect2
- CYP1A1 | c.1519C>A p.Q507K | Missense Mutation (SNP) | VAF 47/143 reads (33%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as COSV65696560; called by muse, mutect2, varscan2
- CYP2A13 | c.164A>G p.Y55C | Missense Mutation (SNP) | VAF 38/235 reads (16%) | SIFT tolerated (0.19); PolyPhen benign (0.028); catalogued as COSV57837714; called by muse, mutect2, varscan2
- DCAF8L1 | c.1186G>A p.V396I | Missense Mutation (SNP) | VAF 47/284 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs754870602, COSV71595106; called by muse, mutect2, varscan2
- DHX32 | c.1882-1G>C p.X628_splice | Splice Site (SNP) | VAF 84/216 reads (39%) | catalogued as COSV52938083; called by muse, mutect2, varscan2
- DIPK2B | c.1186G>T p.D396Y | Missense Mutation (SNP) | VAF 22/185 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.919); catalogued as COSV101211690; called by muse, mutect2, varscan2
- DLAT | c.560C>G p.P187R | Missense Mutation (SNP) | VAF 104/193 reads (54%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as COSV54768978; called by muse, mutect2, varscan2
- DNAH2 | c.2497G>A p.E833K | Missense Mutation (SNP) | VAF 52/586 reads (9%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.838); catalogued as COSV66716117, COSV66717543, COSV66720257; called by muse, mutect2
- DNAH5 | c.3052A>T p.I1018F | Missense Mutation (SNP) | VAF 14/292 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.127); catalogued as COSV54242688; called by muse, mutect2
- DNAJB7 | c.330C>G p.H110Q | Missense Mutation (SNP) | VAF 17/85 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.024); catalogued as COSV53420719, COSV53420815; called by muse, mutect2, varscan2
- DNAJC16 | c.1608G>C p.M536I | Missense Mutation (SNP) | VAF 130/2094 reads (6%) | SIFT tolerated (0.19); PolyPhen benign (0.03); catalogued as COSV65449377; called by muse, mutect2
- DOCK7 | c.1702C>A p.P568T | Missense Mutation (SNP) | VAF 25/110 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99225132; called by muse, mutect2, varscan2
- DSG1 | c.869T>A p.I290N | Missense Mutation (SNP) | VAF 42/110 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV57133109; called by muse, mutect2, varscan2
- DUOX2 | c.1326C>A p.S442R | Missense Mutation (SNP) | VAF 10/106 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as COSV101199818; called by muse, mutect2
- DZIP3 | c.33-2A>G p.X11_splice | Splice Site (SNP) | VAF 14/260 reads (5%) | catalogued as COSV100847920; called by muse, mutect2
- EFCAB7 | c.1174A>T p.R392* | Nonsense Mutation (SNP) | VAF 13/151 reads (9%) | catalogued as COSV100937712; called by muse, mutect2
- EIF4A3 | c.1129G>C p.A377P | Missense Mutation (SNP) | VAF 26/258 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV53919542; called by muse, mutect2, varscan2
- EXOC4 | c.17C>A p.A6D | Missense Mutation (SNP) | VAF 32/181 reads (18%) | SIFT tolerated, low confidence (0.2); PolyPhen probably damaging (0.981); catalogued as COSV54083179; called by muse, mutect2, varscan2
- F5 | c.6586A>T p.I2196F | Missense Mutation (SNP) | VAF 68/218 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63120258; called by mutect2, varscan2
- F5 | c.1180G>T p.V394F | Missense Mutation (SNP) | VAF 18/322 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV100889176; called by muse, mutect2
- FAM171B | c.2296G>T p.G766* | Nonsense Mutation (SNP) | VAF 15/124 reads (12%) | catalogued as COSV59000621; called by muse, mutect2, varscan2
- FLG2 | c.2386C>A p.Q796K | Missense Mutation (SNP) | VAF 202/739 reads (27%) | SIFT tolerated (0.3); PolyPhen benign (0.118); catalogued as COSV66166546; called by muse, mutect2, varscan2
- FTO | c.737G>T p.S246I | Missense Mutation (SNP) | VAF 23/157 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.635); catalogued as COSV101150673; called by muse, mutect2, varscan2
- G6PC | c.910G>A p.V304I | Missense Mutation (SNP) | VAF 177/659 reads (27%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as rs768385469, COSV53830027; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GABRG1 | c.793G>T p.D265Y | Missense Mutation (SNP) | VAF 18/92 reads (20%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.932); catalogued as COSV54951020; called by muse, mutect2, varscan2
- GEMIN5 | c.1252G>T p.V418L | Missense Mutation (SNP) | VAF 28/145 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); catalogued as COSV99594124; called by muse, mutect2, varscan2
- HCFC2 | c.1373C>T p.T458M | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as rs574023442, COSV57557888, COSV57559881; called by muse, mutect2, varscan2
- HTN3 | c.37A>T p.M13L | Missense Mutation (SNP) | VAF 11/156 reads (7%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.003); catalogued as COSV66879359; called by muse, mutect2
- HTR2C | c.163T>A p.W55R | Missense Mutation (SNP) | VAF 47/224 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52201219, COSV52218410; called by muse, mutect2, varscan2
- HTR4 | c.1097G>C p.S366T | Missense Mutation (SNP) | VAF 51/493 reads (10%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0); catalogued as COSV100088839; called by muse, mutect2, varscan2
- HTT | c.4375C>G p.R1459G | Missense Mutation (SNP) | VAF 37/179 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100750992; called by muse, mutect2, varscan2
- IGHG2 | c.315G>C p.E105D | Missense Mutation (SNP) | VAF 521/1059 reads (49%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as rs749303415; called by muse, mutect2, varscan2
- INHA | c.954C>G p.Y318* | Nonsense Mutation (SNP) | VAF 8/252 reads (3%) | catalogued as COSV99217136; called by muse, mutect2
- INTS2 | c.2993G>T p.C998F | Missense Mutation (SNP) | VAF 70/578 reads (12%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.466); catalogued as COSV52150831; called by muse, mutect2, varscan2
- IQSEC1 | c.1070C>A p.T357K | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.9); catalogued as COSV99832114; called by mutect2, varscan2
- IRF8 | c.443A>G p.K148R | Missense Mutation (SNP) | VAF 27/60 reads (45%) | SIFT tolerated (0.14); PolyPhen benign (0.074); catalogued as COSV51896616; called by muse, mutect2, varscan2
- ITGA5 | c.2307C>G p.S769R | Missense Mutation (SNP) | VAF 25/162 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV53215434; called by muse, mutect2, varscan2
- KDM7A | c.2695T>G p.S899A | Missense Mutation (SNP) | VAF 18/337 reads (5%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as COSV99134768; called by muse, mutect2
- KLHDC1 | c.976G>C p.D326H | Missense Mutation (SNP) | VAF 4/91 reads (4%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.995); catalogued as COSV100833582; called by muse, mutect2
- KRBA2 | c.405C>G p.Y135* | Nonsense Mutation (SNP) | VAF 14/237 reads (6%) | catalogued as COSV100497696; called by muse, mutect2
- L3HYPDH | c.619G>C p.A207P | Missense Mutation (SNP) | VAF 13/102 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.025); catalogued as COSV55966491; called by muse, mutect2, varscan2
- LAMC2 | c.1044C>G p.I348M | Missense Mutation (SNP) | VAF 12/254 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99917656; called by muse, mutect2
- LCMT2 | c.717C>G p.N239K | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.154); catalogued as COSV99980144; called by muse, mutect2, varscan2
- LMBR1 | c.908T>C p.I303T | Missense Mutation (SNP) | VAF 14/266 reads (5%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as COSV100626747; called by muse, mutect2
- LMTK3 | c.580C>T p.L194F | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99540831; called by muse, varscan2
- LRP2 | c.10555T>G p.C3519G | Missense Mutation (SNP) | VAF 15/99 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55540323; called by muse, mutect2, varscan2
- LRP2 | c.5749A>T p.N1917Y | Missense Mutation (SNP) | VAF 32/447 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV99789420; called by muse, mutect2
- LSAMP | c.575C>T p.S192L | Missense Mutation (SNP) | VAF 19/360 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.796); catalogued as COSV100371714; called by muse, mutect2
- LUZP4 | c.281A>T p.Q94L | Missense Mutation (SNP) | VAF 14/103 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.833); catalogued as COSV64218370; called by muse, mutect2, varscan2
- MAP2 | c.2653G>T p.D885Y | Missense Mutation (SNP) | VAF 10/100 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV99560871; called by muse, mutect2
- MAP3K6 | c.2372T>G p.F791C | Missense Mutation (SNP) | VAF 9/94 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV100709311; called by muse, mutect2, varscan2
- MATR3 | c.719C>G p.S240W | Missense Mutation (SNP) | VAF 13/96 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); catalogued as COSV63075711; called by muse, mutect2, varscan2
- MEPE | c.1043A>T p.K348M | Missense Mutation (SNP) | VAF 6/119 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as COSV100734973; called by muse, mutect2
- MTOR | c.231C>G p.S77R | Missense Mutation (SNP) | VAF 46/239 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.855); catalogued as COSV100816461; called by muse, mutect2, varscan2
- MTTP | c.2659G>C p.D887H | Missense Mutation (SNP) | VAF 10/192 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.371); catalogued as COSV99645384; called by muse, mutect2
- MTUS2 | c.1585G>T p.V529F | Missense Mutation (SNP) | VAF 13/192 reads (7%) | SIFT tolerated (0.93); PolyPhen benign (0.001); catalogued as COSV101462300; called by muse, mutect2
- MUC17 | c.4561G>T p.V1521F | Missense Mutation (SNP) | VAF 29/412 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.34); catalogued as COSV100074208; called by muse, mutect2
- MYCT1 | c.203T>A p.L68H | Missense Mutation (SNP) | VAF 115/286 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); catalogued as rs1485814836, COSV65890769; called by muse, mutect2, varscan2
- MYH1 | c.2824G>T p.A942S | Missense Mutation (SNP) | VAF 28/618 reads (5%) | SIFT tolerated (0.1); PolyPhen benign (0.082); catalogued as COSV99876386; called by muse, mutect2
- MYH11 | c.4636A>G p.T1546A | Missense Mutation (SNP) | VAF 16/264 reads (6%) | SIFT tolerated (0.43); PolyPhen benign (0.044); catalogued as COSV55545414; called by muse, mutect2
- MYH3 | c.446A>T p.Q149L | Missense Mutation (SNP) | VAF 33/1002 reads (3%) | SIFT deleterious (0.04); PolyPhen benign (0.023); catalogued as COSV99878210; called by muse, mutect2
- MYH4 | c.2445C>G p.I815M | Missense Mutation (SNP) | VAF 64/338 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.01); catalogued as COSV99701698; called by muse, mutect2, varscan2
- MYH7 | c.4076G>A p.R1359H | Missense Mutation (SNP) | VAF 29/76 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as rs750836033, COSV62516140; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NAB2 | c.695G>A p.G232D | Missense Mutation (SNP) | VAF 45/75 reads (60%) | SIFT tolerated (0.66); PolyPhen benign (0.033); catalogued as COSV55665407; called by muse, mutect2, varscan2
- NFE2L3 | c.895G>T p.A299S | Missense Mutation (SNP) | VAF 146/347 reads (42%) | SIFT tolerated (0.64); PolyPhen benign (0.006); catalogued as COSV50226199; called by muse, mutect2, varscan2
- NMS | c.337G>T p.G113C | Missense Mutation (SNP) | VAF 21/172 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.334); catalogued as rs202227228, COSV65258278; called by muse, mutect2, varscan2
- NMUR1 | c.182T>G p.M61R | Missense Mutation (SNP) | VAF 10/72 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.005); catalogued as COSV100532042; called by muse, varscan2
- OR1E1 | c.134T>A p.I45N | Missense Mutation (SNP) | VAF 61/551 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV100491973; called by muse, mutect2, varscan2
- OR1E2 | c.805T>A p.L269I | Missense Mutation (SNP) | VAF 90/299 reads (30%) | SIFT tolerated (0.09); PolyPhen benign (0.189); catalogued as COSV99943467, COSV99943509; called by muse, mutect2, varscan2
- OR2F2 | c.415G>A p.G139R | Missense Mutation (SNP) | VAF 35/216 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.133); catalogued as rs1175463741, COSV101283832, COSV68832872; called by muse, mutect2, varscan2
- OR2J3 | c.204C>A p.N68K | Missense Mutation (SNP) | VAF 150/740 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.104); catalogued as rs201161327, COSV101013642; called by muse, mutect2, varscan2
- OR5D16 | c.491C>A p.S164Y | Missense Mutation (SNP) | VAF 16/216 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.211); catalogued as rs1368285050, COSV101004057; called by muse, mutect2
- OR5T3 | c.279G>T p.M93I | Missense Mutation (SNP) | VAF 12/347 reads (3%) | SIFT deleterious (0.03); PolyPhen benign (0.081); catalogued as COSV57381882; called by muse, mutect2
- OR7D2 | c.523C>T p.P175S | Missense Mutation (SNP) | VAF 30/454 reads (7%) | SIFT tolerated, low confidence (0.09); PolyPhen probably damaging (0.982); catalogued as rs867979852, COSV60140875; called by muse, mutect2
- OTOP3 | c.208C>T p.Q70* | Nonsense Mutation (SNP) | VAF 10/116 reads (9%) | catalogued as COSV100172928; called by muse, mutect2
- PALB2 | c.1547G>T p.R516I | Missense Mutation (SNP) | VAF 41/214 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV99848731; called by muse, mutect2, varscan2
- PAXBP1 | c.597G>C p.K199N | Missense Mutation (SNP) | VAF 9/90 reads (10%) | SIFT tolerated (0.22); PolyPhen benign (0.351); catalogued as COSV99269374; called by muse, mutect2, varscan2
- PDE1B | c.30G>C p.E10D | Missense Mutation (SNP) | VAF 20/98 reads (20%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0); catalogued as COSV99672773; called by muse, mutect2, varscan2
- PDGFRB | c.1891G>A p.V631M | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99940795; called by muse, mutect2, varscan2
- PGAP3 | c.907G>A p.E303K | Missense Mutation (SNP) | VAF 16/83 reads (19%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as COSV99510679; called by muse, mutect2, varscan2
- PIK3CG | c.2706T>G p.F902L | Missense Mutation (SNP) | VAF 12/306 reads (4%) | SIFT tolerated (0.1); PolyPhen benign (0.17); catalogued as COSV100783018; called by muse, mutect2
- PIP5K1A | c.625C>G p.P209A (on ENST00000368888 / NM_001135638.2; = p.P196A on NM_003557.3) | Missense Mutation (SNP) | VAF 64/512 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.588); catalogued as COSV62957332, COSV62957893; called by muse, mutect2, varscan2
- PPFIA4 | c.853C>T p.R285W | Missense Mutation (SNP) | VAF 12/18 reads (67%) | SIFT deleterious (0); PolyPhen possibly damaging (0.677); catalogued as rs766213582, COSV99830225; called by muse, varscan2
- PRKCB | c.542A>C p.K181T | Missense Mutation (SNP) | VAF 30/682 reads (4%) | SIFT tolerated (0.18); PolyPhen benign (0.371); catalogued as COSV100334595; called by muse, mutect2
- PRPS1L1 | c.172A>G p.S58G | Missense Mutation (SNP) | VAF 194/1696 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.821); catalogued as COSV72649790; called by muse, mutect2, varscan2
- PTPN13 | c.7103T>C p.I2368T (on ENST00000411767 / NM_080683.3; = p.I2349T on NM_006264.3) | Missense Mutation (SNP) | VAF 47/185 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV57402230; called by muse, mutect2, varscan2
- PTPRG | c.2566C>A p.Q856K | Missense Mutation (SNP) | VAF 30/115 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.005); catalogued as COSV55628232; called by muse, mutect2, varscan2
- RAB3B | c.473G>A p.G158E | Missense Mutation (SNP) | VAF 57/295 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as COSV100862520; called by muse, mutect2, varscan2
- RBM43 | c.538T>C p.F180L | Missense Mutation (SNP) | VAF 35/444 reads (8%) | SIFT tolerated (0.29); PolyPhen benign (0.011); catalogued as COSV100508603; called by muse, mutect2
- RGS12 | c.1517C>G p.S506C | Missense Mutation (SNP) | VAF 22/61 reads (36%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.613); catalogued as COSV60902068; called by muse, mutect2, varscan2
- RNF113A | c.760G>C p.D254H | Missense Mutation (SNP) | VAF 18/117 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV101007078; called by muse, mutect2, varscan2
- RNF216 | c.532T>G p.F178V (on ENST00000425013 / NM_207116.3; = p.F235V on NM_207111.4) | Missense Mutation (SNP) | VAF 26/111 reads (23%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.053); catalogued as COSV66288961; called by muse, mutect2, varscan2
- RTP3 | c.530C>A p.P177Q | Missense Mutation (SNP) | VAF 5/75 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV56123529; called by muse, mutect2
- RUFY1 | c.1366C>G p.L456V | Missense Mutation (SNP) | VAF 46/130 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.224); catalogued as COSV60158280; called by muse, mutect2, varscan2
- RUSF1 | c.785G>A p.G262E | Missense Mutation (SNP) | VAF 6/71 reads (8%) | SIFT tolerated (0.24); PolyPhen benign (0.026); catalogued as COSV57890041; called by muse, mutect2
- RYR1 | c.12465T>G p.H4155Q | Missense Mutation (SNP) | VAF 91/540 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.368); catalogued as COSV100616276; called by muse, mutect2, varscan2
- SCD5 | c.291G>A p.W97* | Nonsense Mutation (SNP) | VAF 47/108 reads (44%) | catalogued as COSV51101850; called by muse, mutect2, varscan2
- SCN7A | c.4985C>T p.A1662V | Missense Mutation (SNP) | VAF 51/712 reads (7%) | SIFT tolerated (0.24); PolyPhen benign (0.015); catalogued as rs369467319; called by muse, mutect2
- SERPINA4 | c.171C>A p.D57E | Missense Mutation (SNP) | VAF 16/456 reads (4%) | SIFT tolerated (0.29); PolyPhen benign (0.331); catalogued as rs1160359144, COSV100097320; called by muse, mutect2
- SERPINB12 | c.113C>T p.A38V | Missense Mutation (SNP) | VAF 42/824 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV99501744; called by muse, mutect2
- SERPINE1 | c.356C>T p.A119V | Missense Mutation (SNP) | VAF 205/1825 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.755); catalogued as rs143027028; called by muse, mutect2, varscan2
- SEZ6L2 | c.142T>A p.S48T | Missense Mutation (SNP) | VAF 32/49 reads (65%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV58097082; called by muse, mutect2, varscan2
- SF3A1 | c.304A>T p.K102* | Nonsense Mutation (SNP) | VAF 42/294 reads (14%) | catalogued as COSV53167139; called by muse, mutect2, varscan2
- SH3BP4 | c.1241A>C p.Q414P | Missense Mutation (SNP) | VAF 7/77 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.054); catalogued as COSV100749253; called by muse, mutect2, varscan2
- SIGLEC5 | c.1318G>A p.A440T | Missense Mutation (SNP) | VAF 18/460 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.941); catalogued as COSV99707690; called by muse, mutect2
- SKA3 | c.995T>A p.L332* | Nonsense Mutation (SNP) | VAF 9/163 reads (6%) | catalogued as COSV100006430; called by muse, mutect2
- SLC2A4 | c.34G>A p.D12N | Missense Mutation (SNP) | VAF 46/746 reads (6%) | SIFT tolerated (0.16); PolyPhen benign (0.014); catalogued as rs562894482, COSV100435289, COSV100435302; called by muse, mutect2
- SLC44A4 | c.905A>G p.Y302C | Missense Mutation (SNP) | VAF 22/104 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV57665725; called by muse, mutect2, varscan2
- SLC51B | c.361C>G p.P121A | Missense Mutation (SNP) | VAF 5/103 reads (5%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.849); catalogued as COSV99585059; called by muse, mutect2
- SMAP2 | c.692C>A p.S231Y | Missense Mutation (SNP) | VAF 28/788 reads (4%) | SIFT deleterious (0.03); PolyPhen benign (0.353); catalogued as COSV101019151; called by muse, mutect2
- SYN3 | c.366G>T p.E122D | Missense Mutation (SNP) | VAF 73/1585 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV60503400; called by muse, mutect2
- SYNE1 | c.5851A>G p.T1951A (on ENST00000367255 / NM_182961.4; = p.T1958A on NM_033071.3) | Missense Mutation (SNP) | VAF 16/282 reads (6%) | SIFT tolerated (0.24); PolyPhen benign (0.006); catalogued as COSV55034945, COSV99571550; called by muse, mutect2
- SYTL2 | c.1255G>C p.G419R | Missense Mutation (SNP) | VAF 169/354 reads (48%) | SIFT tolerated (0.05); PolyPhen benign (0.003); catalogued as COSV100313827, COSV100314544; called by mutect2, varscan2
- SYTL4 | c.1101G>C p.E367D | Missense Mutation (SNP) | VAF 30/201 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV52165292; called by muse, mutect2, varscan2
- TACC2 | c.1223C>T p.S408F | Missense Mutation (SNP) | VAF 34/68 reads (50%) | SIFT deleterious (0.02); PolyPhen benign (0.005); catalogued as COSV57745822; called by muse, mutect2, varscan2
- TADA1 | c.451C>G p.L151V | Missense Mutation (SNP) | VAF 145/415 reads (35%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.806); catalogued as COSV63309816; called by muse, mutect2, varscan2
- TBC1D8B | c.1373A>T p.E458V | Missense Mutation (SNP) | VAF 12/112 reads (11%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.938); catalogued as COSV99344686; called by muse, varscan2
- TBK1 | c.543C>G p.H181Q | Missense Mutation (SNP) | VAF 8/119 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV100538254; called by muse, mutect2
- TDP2 | c.207C>A p.S69R | Missense Mutation (SNP) | VAF 182/294 reads (62%) | SIFT tolerated (0.5); PolyPhen benign (0.003); catalogued as COSV57763418; called by muse, mutect2, varscan2
- TFAP2D | c.1240A>T p.T414S | Missense Mutation (SNP) | VAF 25/300 reads (8%) | SIFT tolerated (0.83); PolyPhen benign (0.003); catalogued as COSV50408236; called by muse, mutect2
- TG | c.3896A>T p.Q1299L | Missense Mutation (SNP) | VAF 12/133 reads (9%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99601952; called by muse, mutect2
- TJP3 | c.109A>C p.M37L | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as COSV99516302; called by muse, mutect2, varscan2
- TKTL1 | c.548A>T p.N183I | Missense Mutation (SNP) | VAF 42/259 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); catalogued as COSV99474050; called by muse, mutect2, varscan2
- TLE4 | c.1618A>T p.R540* | Nonsense Mutation (SNP) | VAF 41/105 reads (39%) | catalogued as COSV99512578; called by muse, mutect2, varscan2
- TLN1 | c.4632G>C p.K1544N | Missense Mutation (SNP) | VAF 29/299 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100147952; called by muse, mutect2
- TMEFF1 | c.217G>A p.D73N | Missense Mutation (SNP) | VAF 19/389 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as COSV100614848; called by muse, mutect2
- TMTC2 | c.122C>G p.T41S | Missense Mutation (SNP) | VAF 45/350 reads (13%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.573); catalogued as COSV100338415; called by muse, mutect2, varscan2
- TNC | c.4312G>C p.E1438Q | Missense Mutation (SNP) | VAF 16/414 reads (4%) | SIFT tolerated (0.31); PolyPhen benign (0.097); catalogued as COSV100406015; called by muse, mutect2
- TOX4 | c.1642G>A p.V548I | Missense Mutation (SNP) | VAF 54/592 reads (9%) | SIFT tolerated (0.29); PolyPhen benign (0.007); catalogued as COSV52967850, COSV99398435; called by muse, mutect2
- TPMT | c.326A>G p.E109G | Missense Mutation (SNP) | VAF 11/166 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100015467; called by muse, mutect2
- TRIM39 | c.1306G>A p.G436R | Missense Mutation (SNP) | VAF 29/114 reads (25%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.679); catalogued as COSV64954892; called by muse, mutect2, varscan2
- TRMT44 | c.1310G>T p.R437M | Missense Mutation (SNP) | VAF 32/130 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.936); catalogued as COSV67663319; called by muse, mutect2, varscan2
- TSGA13 | c.430C>T p.P144S | Missense Mutation (SNP) | VAF 7/137 reads (5%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.928); catalogued as COSV100449686; called by muse, mutect2
- TTC4 | c.777G>C p.E259D | Missense Mutation (SNP) | VAF 10/171 reads (6%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as COSV100988444; called by muse, mutect2
- TTN | c.51218C>T p.P17073L (on ENST00000591111; = p.P9649L on NM_003319.4) | Missense Mutation (SNP) | VAF 160/259 reads (62%) | PolyPhen probably damaging (0.999); catalogued as COSV59878825; called by muse, mutect2, varscan2
- UBAP2 | c.1030G>A p.V344I | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT tolerated (0.16); PolyPhen benign (0.099); catalogued as rs780923321, COSV62545098; called by muse, mutect2, varscan2
- UBE3D | c.654G>C p.E218D | Missense Mutation (SNP) | VAF 22/544 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.894); catalogued as COSV99388757; called by muse, mutect2
- USH2A | c.10077T>A p.C3359* | Nonsense Mutation (SNP) | VAF 31/199 reads (16%) | catalogued as COSV56326091; called by muse, mutect2, varscan2
- VCP | c.2218A>G p.M740V | Missense Mutation (SNP) | VAF 34/1088 reads (3%) | SIFT tolerated (0.05); PolyPhen benign (0.078); catalogued as COSV100734271; called by muse, mutect2
- VEPH1 | c.2323G>C p.V775L | Missense Mutation (SNP) | VAF 9/196 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.372); catalogued as COSV100747758; called by muse, mutect2
- VPS13D | c.11485G>C p.V3829L | Missense Mutation (SNP) | VAF 26/875 reads (3%) | SIFT tolerated (0.27); PolyPhen benign (0.009); catalogued as COSV99167511; called by muse, mutect2
- WDR62 | c.333-1G>C p.X111_splice | Splice Site (SNP) | VAF 57/731 reads (8%) | catalogued as COSV99543895; called by muse, mutect2
- WFDC12 | c.61G>A p.V21M | Missense Mutation (SNP) | VAF 17/317 reads (5%) | SIFT tolerated (0.05); PolyPhen benign (0.037); catalogued as COSV100859099; called by muse, mutect2
- YTHDF1 | c.598G>A p.V200I | Missense Mutation (SNP) | VAF 17/80 reads (21%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.46); catalogued as rs374927858; called by muse, mutect2, varscan2
- ZBTB49 | c.871G>C p.D291H | Missense Mutation (SNP) | VAF 22/173 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.862); catalogued as COSV61924238; called by muse, mutect2, varscan2
- ZFAND2B | c.395A>G p.H132R | Missense Mutation (SNP) | VAF 20/254 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99202458; called by muse, mutect2
- ZKSCAN1 | c.769C>G p.Q257E | Missense Mutation (SNP) | VAF 30/138 reads (22%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.682); catalogued as COSV60872961; called by muse, varscan2
- ZNF318 | c.2251A>G p.R751G | Missense Mutation (SNP) | VAF 50/750 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV100546358; called by muse, mutect2
- ZNF346 | c.780del p.F261Sfs*48 | Frame Shift Del (DEL) | VAF 132/560 reads (24%) | catalogued as COSV56155580; called by mutect2, pindel, varscan2
- ZNF711 | c.1729C>A p.L577I | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.015); catalogued as COSV52151264; called by muse, mutect2, varscan2
- ZSWIM4 | c.1234C>T p.H412Y | Missense Mutation (SNP) | VAF 15/256 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV99585112; called by muse, mutect2
- ARMCX2 | c.1046_1047del p.E349Vfs*6 | Frame Shift Del (DEL) | VAF 8/80 reads (10%) | called by pindel, varscan2
- CCDC88B | c.497_517del p.E166_A172del | In Frame Del (DEL) | VAF 4/40 reads (10%) | called by mutect2, pindel
- CLRN2 | c.668_673del p.A223_T224del | In Frame Del (DEL) | VAF 59/427 reads (14%) | called by mutect2, pindel, varscan2
- CNKSR3 | c.1176_1181del p.S392_R393del | In Frame Del (DEL) | VAF 106/397 reads (27%) | called by mutect2, pindel, varscan2
- EXOSC2 | c.215T>A p.L72* | Nonsense Mutation (SNP) | VAF 8/197 reads (4%) | called by muse, mutect2
- FCGBP | c.1760T>A p.V587D | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- FRG2B | c.329_331+4del p.X110_splice | Splice Site (DEL) | VAF 35/112 reads (31%) | called by mutect2, pindel, varscan2
- IGHD | c.1105A>G p.S369G | Missense Mutation (SNP) | VAF 2/17 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.288); called by muse, mutect2
- IGSF10 | c.6941_6963del p.V2314Efs*19 | Frame Shift Del (DEL) | VAF 60/664 reads (9%) | called by mutect2, pindel
- KIAA1755 | c.895G>T p.G299W | Missense Mutation (SNP) | VAF 12/332 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.841); called by muse, mutect2
- KIR2DL4 | c.395G>C p.G132A (on ENST00000396284; = p.G93A on NM_001080770.2) | Missense Mutation (SNP) | VAF 60/577 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, varscan2
- MYH9 | c.2809_2823del p.E937_M941del | In Frame Del (DEL) | VAF 8/24 reads (33%) | called by mutect2, pindel, varscan2
- MYT1L | c.1866_1913del p.N622_E637del | In Frame Del (DEL) | VAF 16/190 reads (8%) | called by mutect2, pindel
- OR5L2 | c.467_469delinsTT p.S156Ffs*2 | Frame Shift Del (DEL) | VAF 86/956 reads (9%) | called by pindel, varscan2*
- RCAN2 | c.423del p.K141Nfs*2 | Frame Shift Del (DEL) | VAF 25/236 reads (11%) | called by mutect2, pindel, varscan2
- RINT1 | c.754_760del p.V252* | Frame Shift Del (DEL) | VAF 65/596 reads (11%) | called by pindel, varscan2
- SLC9A8 | c.570-11_577del p.X190_splice | Splice Site (DEL) | VAF 69/444 reads (16%) | called by mutect2, pindel, varscan2
- SPTAN1 | c.2865del p.C956Afs*33 | Frame Shift Del (DEL) | VAF 78/168 reads (46%) | called by mutect2, pindel, varscan2
- SULF2 | c.1729_1736dup p.G580Rfs*23 | Frame Shift Ins (INS) | VAF 8/65 reads (12%) | called by mutect2, varscan2
- TRIO | c.8206_8210+12del p.X2736_splice | Splice Site (DEL) | VAF 15/65 reads (23%) | called by mutect2, pindel
- WDR46 | c.1824del p.F608Lfs*? | Frame Shift Del (DEL) | VAF 57/185 reads (31%) | called by mutect2, pindel, varscan2
- ACTBL2 | c.927C>T p.G309= | Silent (SNP) | VAF 16/102 reads (16%) | catalogued as COSV101379385; called by muse, mutect2, varscan2
- ADCY5 | c.3741C>T p.G1247= | Silent (SNP) | VAF 30/263 reads (11%) | catalogued as rs751586992, COSV100568005; called by muse, mutect2, varscan2
- ADH1A | c.252C>T p.V84= | Silent (SNP) | VAF 63/483 reads (13%) | catalogued as COSV52924253; called by muse, mutect2, varscan2
- ANAPC4 | c.1896A>G p.R632= | Silent (SNP) | VAF 13/47 reads (28%) | catalogued as rs779121653, COSV59542879; called by muse, mutect2, varscan2
- AQP10 | c.381G>A p.Q127= | Silent (SNP) | VAF 31/212 reads (15%) | catalogued as rs753161641, COSV100270349; called by muse, mutect2, varscan2
- BRD9 | c.1551T>G p.P517= | Silent (SNP) | VAF 31/168 reads (18%) | catalogued as COSV100057350; called by muse, mutect2, varscan2
- C7orf31 | c.729A>G p.K243= | Silent (SNP) | VAF 9/119 reads (8%) | catalogued as rs1277655215, COSV52219709, COSV99384047; called by muse, mutect2
- CD3E | c.201C>T p.G67= | Silent (SNP) | VAF 48/666 reads (7%) | catalogued as rs188934551; called by muse, mutect2
- CHD6 | c.5181T>C p.N1727= | Silent (SNP) | VAF 14/75 reads (19%) | catalogued as rs757480003, COSV64696421; called by muse, mutect2, varscan2
- CILP2 | c.828C>T p.N276= | Silent (SNP) | VAF 10/72 reads (14%) | catalogued as rs758810311, COSV99364952; called by muse, mutect2, varscan2
- CLPTM1 | c.90C>T p.S30= | Silent (SNP) | VAF 11/144 reads (8%) | catalogued as rs972269167, COSV100493869; called by muse, mutect2
- CR1 | c.2673C>A p.P891= | Silent (SNP) | VAF 72/206 reads (35%) | catalogued as COSV65455704, COSV65456410; called by muse, mutect2, varscan2
- DDR2 | c.117C>T p.G39= | Silent (SNP) | VAF 96/225 reads (43%) | catalogued as COSV63369196; called by muse, mutect2, varscan2
- DGKK | c.2379T>C p.S793= | Silent (SNP) | VAF 24/532 reads (5%) | catalogued as COSV101053106; called by muse, mutect2
- DLL4 | c.663C>T p.I221= | Silent (SNP) | VAF 24/54 reads (44%) | catalogued as COSV99989903; called by muse, mutect2, varscan2
- DNAJB8 | c.402C>T p.F134= | Silent (SNP) | VAF 9/94 reads (10%) | catalogued as rs1393827021, COSV100048416; called by muse, mutect2, varscan2
- DPPA4 | c.303C>A p.A101= | Silent (SNP) | VAF 66/627 reads (11%) | catalogued as COSV100169552; called by muse, mutect2, varscan2
- ENTHD1 | c.81C>T p.N27= | Silent (SNP) | VAF 89/303 reads (29%) | catalogued as rs146928757; called by muse, mutect2, varscan2
- EPHA5 | c.1830C>T p.C610= | Silent (SNP) | VAF 20/98 reads (20%) | catalogued as rs200675919, COSV56630556; called by muse, mutect2, varscan2
- FLRT2 | c.1827C>T p.I609= | Silent (SNP) | VAF 102/379 reads (27%) | catalogued as rs1355606166, COSV58136058; called by muse, mutect2, varscan2
- GAB4 | c.609G>A p.P203= | Silent (SNP) | VAF 10/28 reads (36%) | catalogued as rs545946229, COSV68753009; called by muse, mutect2, varscan2
- GBF1 | c.429G>C p.L143= | Silent (SNP) | VAF 52/184 reads (28%) | catalogued as COSV64142683; called by muse, mutect2, varscan2
- H2BC8 | c.117C>T p.S39= | Silent (SNP) | VAF 42/448 reads (9%) | catalogued as COSV55127474, COSV99773293; called by muse, mutect2
- HLA-DRA | c.423G>A p.V141= | Silent (SNP) | VAF 38/448 reads (8%) | catalogued as COSV100895087; called by muse, mutect2
- HMGCS2 | c.1260C>T p.F420= | Silent (SNP) | VAF 19/123 reads (15%) | catalogued as rs15609, COSV65567095; called by muse, mutect2, varscan2
- IFIH1 | c.2068C>T p.L690= | Silent (SNP) | VAF 10/258 reads (4%) | called by muse, mutect2
- IGHD | c.1104C>A p.A368= | Silent (SNP) | VAF 2/18 reads (11%) | called by muse, mutect2
- IKZF4 | c.1206C>T p.V402= | Silent (SNP) | VAF 25/257 reads (10%) | catalogued as COSV56267159; called by muse, mutect2
- ITLN1 | c.537G>T p.L179= | Silent (SNP) | VAF 57/565 reads (10%) | catalogued as COSV58273794; called by muse, mutect2, varscan2
- KLKB1 | c.1560C>A p.T520= | Silent (SNP) | VAF 15/37 reads (41%) | catalogued as COSV52993811; called by muse, mutect2, varscan2
- LAMA1 | c.8706T>A p.A2902= | Silent (SNP) | VAF 7/119 reads (6%) | catalogued as COSV101056955; called by muse, mutect2
- LPA | c.5235T>A p.A1745= | Silent (SNP) | VAF 113/279 reads (41%) | catalogued as COSV100307427; called by muse, mutect2, varscan2
- MAPRE3 | c.24A>G p.T8= | Silent (SNP) | VAF 133/640 reads (21%) | catalogued as COSV51866232; called by muse, mutect2, varscan2
- MATN3 | c.303A>G p.K101= | Silent (SNP) | VAF 10/47 reads (21%) | catalogued as COSV101337460; called by muse, mutect2, varscan2
- MED12L | c.1812C>T p.C604= | Silent (SNP) | VAF 26/279 reads (9%) | catalogued as rs762849776, COSV99853855; called by muse, mutect2
- MUC16 | c.42249C>T p.I14083= | Silent (SNP) | VAF 30/298 reads (10%) | catalogued as COSV101109849, COSV66689721; called by muse, mutect2, varscan2
- NIM1K | c.1017G>C p.L339= | Silent (SNP) | VAF 24/392 reads (6%) | catalogued as COSV100390279; called by muse, mutect2
- OR10AG1 | c.582G>A p.A194= | Silent (SNP) | VAF 13/102 reads (13%) | catalogued as rs556408380, COSV56631333; called by muse, mutect2, varscan2
- OR10C1 | c.381C>T p.I127= (on ENST00000622521; = p.I125= on NM_013941.3) | Silent (SNP) | VAF 25/346 reads (7%) | catalogued as COSV101010859; called by muse, mutect2
- OR52A5 | c.534T>A p.S178= | Silent (SNP) | VAF 29/372 reads (8%) | catalogued as COSV100263499; called by muse, mutect2
- OR5I1 | c.177C>T p.T59= | Silent (SNP) | VAF 18/173 reads (10%) | catalogued as rs750061398, COSV56885342; called by muse, mutect2, varscan2
- OR5M3 | c.495C>T p.Y165= | Silent (SNP) | VAF 49/456 reads (11%) | called by muse, varscan2
- PASD1 | c.2034A>T p.S678= | Silent (SNP) | VAF 131/359 reads (36%) | catalogued as COSV64854033; called by muse, mutect2, varscan2
- PIWIL2 | c.1428C>T p.P476= | Silent (SNP) | VAF 13/98 reads (13%) | called by muse, mutect2, varscan2
- PKHD1 | c.4170G>T p.R1390= | Silent (SNP) | VAF 125/257 reads (49%) | catalogued as COSV61859948, COSV61860734; called by muse, mutect2, varscan2
- POLK | c.735A>G p.E245= | Silent (SNP) | VAF 6/74 reads (8%) | catalogued as COSV99606201; called by muse, mutect2
- PON3 | c.357C>T p.F119= | Silent (SNP) | VAF 22/268 reads (8%) | catalogued as COSV55699907; called by muse, mutect2
- PREPL | c.2124G>A p.E708= | Silent (SNP) | VAF 7/92 reads (8%) | catalogued as COSV99576306; called by muse, mutect2
- PTPN4 | c.117T>A p.T39= | Silent (SNP) | VAF 30/210 reads (14%) | catalogued as COSV55297209; called by muse, mutect2, varscan2
- RBP3 | c.105C>G p.L35= | Silent (SNP) | VAF 3/44 reads (7%) | called by muse, mutect2
- RESF1 | c.3420C>T p.I1140= | Silent (SNP) | VAF 28/217 reads (13%) | catalogued as COSV100440447; called by muse, mutect2, varscan2
- RPS3A | c.525G>A p.E175= | Silent (SNP) | VAF 10/78 reads (13%) | catalogued as COSV56838949; called by muse, mutect2, varscan2
- RYR2 | c.3237C>T p.S1079= | Silent (SNP) | VAF 15/137 reads (11%) | catalogued as rs770116364, COSV63676503; called by mutect2, varscan2
- SCP2D1 | c.363C>A p.G121= | Silent (SNP) | VAF 10/123 reads (8%) | catalogued as COSV99601994, COSV99602136; called by muse, mutect2
- SLC35B2 | c.33G>A p.L11= | Silent (SNP) | VAF 26/282 reads (9%) | catalogued as COSV51487425; called by muse, mutect2
- SLITRK3 | c.282C>A p.T94= | Silent (SNP) | VAF 27/209 reads (13%) | catalogued as COSV53845500; called by muse, mutect2, varscan2
- SP100 | c.2443T>C p.L815= | Silent (SNP) | VAF 48/207 reads (23%) | catalogued as COSV60841365; called by muse, mutect2, varscan2
- SPEF2 | c.2025T>C p.D675= | Silent (SNP) | VAF 7/62 reads (11%) | catalogued as COSV100608050; called by muse, mutect2, varscan2
- SUN2 | c.1140C>G p.A380= | Silent (SNP) | VAF 7/53 reads (13%) | catalogued as COSV99325712; called by muse, mutect2, varscan2
- TP53BP2 | c.1878A>G p.G626= (on ENST00000343537 / NM_001031685.3; = p.G497= on NM_005426.2) | Silent (SNP) | VAF 22/413 reads (5%) | catalogued as COSV100636708, COSV59066347; called by muse, mutect2
- TRABD2A | c.981C>G p.A327= (on ENST00000409520 / NM_001277053.2; = p.A278= on NM_001080824.3) | Silent (SNP) | VAF 14/294 reads (5%) | catalogued as COSV100120035; called by muse, mutect2
- TRBV28 | c.117T>C p.F39= | Silent (SNP) | VAF 42/137 reads (31%) | called by muse, mutect2, varscan2
- TTN | c.55923C>T p.D18641= (on ENST00000591111; = p.D11217= on NM_003319.4) | Silent (SNP) | VAF 31/287 reads (11%) | catalogued as COSV100620628; called by muse, mutect2, varscan2
- UBE4B | c.3582G>C p.G1194= (on ENST00000343090 / NM_001105562.3; = p.G1065= on NM_006048.5) | Silent (SNP) | VAF 47/85 reads (55%) | catalogued as COSV53526997; called by muse, mutect2, varscan2
- WASHC2C | c.1584A>T p.S528= | Silent (SNP) | VAF 12/302 reads (4%) | catalogued as COSV100314113; called by muse, mutect2
- WWP2 | c.1416T>C p.F472= | Silent (SNP) | VAF 31/96 reads (32%) | catalogued as COSV100598656; called by muse, mutect2, varscan2
- ZNF511 | c.447A>G p.E149= | Silent (SNP) | VAF 47/82 reads (57%) | catalogued as COSV100756842; called by muse, mutect2, varscan2
- ZSCAN2 | c.432G>C p.G144= | Silent (SNP) | VAF 237/467 reads (51%) | catalogued as COSV57571822; called by muse, mutect2, varscan2
- ZSCAN5B | c.363T>C p.N121= | Silent (SNP) | VAF 38/422 reads (9%) | catalogued as COSV62838333; called by muse, mutect2
- AC005863.1 | n.328T>A | RNA (SNP) | VAF 54/193 reads (28%) | called by muse, mutect2, varscan2
- AC074085.2 | n.228T>C | RNA (SNP) | VAF 27/152 reads (18%) | called by muse, mutect2, varscan2
- AP000769.3 | chr11:65506353 G>T | 3'Flank (SNP) | VAF 8/59 reads (14%) | called by muse, mutect2, varscan2
- CCDC144B | n.272C>T | RNA (SNP) | VAF 4/24 reads (17%) | called by mutect2, varscan2
- CCDC33 | c.2139+10C>A | Intron (SNP) | VAF 68/529 reads (13%) | catalogued as COSV51430554, COSV99166121; called by muse, mutect2, varscan2
- EI24P4 | n.1041A>G | RNA (SNP) | VAF 25/643 reads (4%) | called by muse, mutect2
- MRPL11 | c.473+260C>G | Intron (SNP) | VAF 83/451 reads (18%) | catalogued as COSV100207802; called by muse, mutect2, varscan2
- SNORD116-16 | n.52A>G | RNA (SNP) | VAF 203/1025 reads (20%) | called by muse, mutect2, varscan2
